TCGA case TCGA-02-0087 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9a4b35cb-99dc-4343-a08e-25c3c8693243

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 27 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 27.9 years (10,185 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 32.7 years (11,942 days); Days to diagnosis: 1,757 days (4.8 years); Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 1,757 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,757 days (4.8 years).
- Karnofsky performance status: 80.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.1.
  Slide TCGA-02-0087-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-02-0087-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,757 days; disease-specific survival: no event (censored), 1,757 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,757 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0087-01): tumor purity 0.72, ploidy 2.07, whole-genome doublings 0 (call status: legacy_call).
